Somatic mutation profile of tumor specimen 0DB982 from CCDI case PBBKXM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.8 years (6,512 days).
Specimen 0DB982: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ab4cbc6-bf23-4f74-a12d-a197576fb70f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DB97Q (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05496e06-2f14-4a58-a3ca-443fed8b222f

The open-access MAF lists 6 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Intron 1, In Frame Ins 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1914_1916dup p.T639dup (on ENST00000288602 / NM_001374244.1; = p.T599dup on NM_004333.6 and 3 other RefSeq transcripts) | In Frame Ins (INS) | VAF 195/737 reads (26%) | catalogued as rs727502902; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KAT6A | c.553_554del p.L185Ffs*12 | Frame Shift Del (DEL) | VAF 114/797 reads (14%) | called by pindel, varscan2
- CES3 | c.774C>T p.I258= | Silent (SNP) | VAF 133/814 reads (16%) | catalogued as COSV57593621; called by muse, mutect2, varscan2
- ZFAT | c.555A>G p.S185= | Silent (SNP) | VAF 213/1034 reads (21%) | called by muse, mutect2, varscan2
- CACNA1G | c.-22C>T | 5'UTR (SNP) | VAF 48/257 reads (19%) | catalogued as rs1489618655; called by muse, mutect2, varscan2
- CYP21A2 | c.651+39G>A | Intron (SNP) | VAF 21/747 reads (3%) | called by muse, mutect2
